Gene-level copy-number profile of tumor specimen TCGA-SN-A84X-01A from TCGA case TCGA-SN-A84X, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 21.4 years (7,833 days).
Specimen TCGA-SN-A84X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.54c30b5b-13aa-40fb-93a0-462918628fe4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SN-A84X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17a98514-8b2f-4a38-b8c2-c4a4ea3ce0a1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 75; copy number 3: 345; copy number 4: 33,031; copy number 5: 2,402; copy number 6: 19,241; copy number 7: 72; copy number 8: 2,180; copy number 9: 647; copy number 10: 97; copy number 11: 679; copy number 13: 992; copy number 14: 34; copy number 16: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SN-A84X-01A-11D-A434-01): tumor purity 0.75, ploidy 2.54, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,460 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,622,885–202,592,706, 36 genes, copy number 9 (within-gene range 6–9): NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6, UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2, SNORA70.
- chr7:5,526,409–6,589,374, 34 genes, copy number 14 (within-gene range 6–14): ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1.
- chr8:43,672,823–98,942,827, 805 genes, copy number 11–13 (within-gene range 8–13) (broad region; genes not listed).
- chr12:66,767–38,909,592, 866 genes, copy number 13 (broad region; genes not listed).
- chr16:46,469,341–69,085,182, 557 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr22:20,441,519–20,495,844, 1 gene, copy number 16 (within-gene range 7–16): KLHL22.
- chr22:20,475,203–22,043,934, 98 genes, copy number 10–16 (broad region; genes not listed).
- chr22:22,043,618–22,088,085, 9 genes, copy number 10: IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5.
- chr22:23,322,543–24,178,628, 54 genes, copy number 9 (within-gene range 8–9): AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4, DRICH1, AP000346.3, AP000346.1, GUSBP11, AP000346.2, ASLP1, AP000347.1, RGL4, ZNF70, VPREB3, C22orf15, CHCHD10, MMP11, SMARCB1, DERL3, AP000350.5, SLC2A11, AP000350.4, AP000350.8, RN7SL268P, MIF, MIF-AS1, AP000350.6, AP000350.2, AP000350.1, AP000350.3, GSTT2B, AC253536.2, DDTL, AC253536.6, DDT, AC253536.7, AC253536.1, AC253536.5, GSTT2, GSTT4, AC253536.4, CABIN1, AC253536.3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
